Gene-level copy-number profile of tumor specimen TARGET-10-PATGZA-09A from TARGET case TARGET-10-PATGZA, project TARGET-ALL-P2 (Acute Lymphoblastic Leukemia - Phase II). Sex at birth: female; Vital status: Alive; Primary diagnosis: Acute lymphocytic leukemia; Tissue or organ of origin: Bone marrow; Age at diagnosis: 14.4 years (5,253 days).
Specimen TARGET-10-PATGZA-09A: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TARGET-ALL-P2.0bee8c32-3e76-52a2-9c5c-cb24dfe499b0.gene_level_copy_number.v36.tsv, workflow ASCAT2 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TARGET-10-PATGZA-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 350 have no estimate.
https://portal.gdc.cancer.gov/files/37e262ee-6ac5-475b-8a5d-fe81ba1441ce

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 520; copy number 1: 566; copy number 2: 55,820; copy number 3: 3,364; copy number 4: 3.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): none.

Autosomal genes at a single copy (total copy number 1): 559. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
